Somatic mutation profile of tumor specimen SM-JU34O (aliquot 7316UP-483) from CPTAC case C223491, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS.
Specimen SM-JU34O: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b3f0ce0-22aa-4f9e-befd-7a0a1a155cf1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105289 (Blood Derived Normal), aliquot 7316UP-483-1105289; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50853352-fcba-43ca-a3b8-2e18ea9662c7

The open-access MAF lists 1,307 somatic variants for this specimen: 875 protein-altering or splice-affecting, 262 silent, 170 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 577, Silent 262, Frame Shift Del 196, Intron 90, Frame Shift Ins 35, 3'UTR 31, Nonsense Mutation 28, RNA 17, Splice Site 16, 5'Flank 13, 5'UTR 13, Splice Region 11.

Variants (750 of 1,307; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 104/317 reads (33%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, varscan2
- ABCB4 | c.1015del p.S339Qfs*3 | Frame Shift Del (DEL) | VAF 97/296 reads (33%) | catalogued as rs753104429, CD034702, COSV55939298; ClinVar: pathogenic; called by mutect2, varscan2
- APOA1 | c.85dup p.Q29Pfs*30 | Frame Shift Ins (INS) | VAF 45/206 reads (22%) | catalogued as rs753348565; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KAT6A | c.4645G>A p.G1549S | Missense Mutation (SNP) | VAF 115/331 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1064794000, COSV55907802; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 113/277 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- MYO7A | c.6487G>A p.G2163S | Missense Mutation (SNP) | VAF 142/346 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs747656448, CM990906, COSV60020751; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 49/117 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTCH1 | c.114dup p.L39Afs*51 | Frame Shift Ins (INS) | VAF 122/331 reads (37%) | catalogued as rs751977093; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 176/436 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 100/326 reads (31%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RHOA | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 115/351 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV69041545, COSV69041670; called by muse, mutect2, varscan2
- SLCO2A1 | c.830del p.F277Sfs*8 | Frame Shift Del (DEL) | VAF 106/420 reads (25%) | catalogued as rs751192029; ClinVar: pathogenic; called by mutect2, varscan2
- WRN | c.3382del p.S1128Vfs*34 | Frame Shift Del (DEL) | VAF 32/105 reads (30%) | catalogued as rs778872619; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA5 | c.426del p.P143Lfs*3 | Frame Shift Del (DEL) | VAF 43/132 reads (33%) | catalogued as COSV67018434; called by mutect2, pindel, varscan2
- ABCC9 | c.622C>A p.L208I | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV53965219; called by muse, mutect2, varscan2
- ACADL | c.272A>G p.E91G | Missense Mutation (SNP) | VAF 177/435 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs1319500123, COSV52055319; called by muse, mutect2, varscan2
- ACE | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 92/446 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs199746395, COSV52007723; called by muse, mutect2, varscan2
- ADAM22 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 78/216 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55970780, COSV99718649; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4595G>A p.R1532H | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as rs747642979, COSV65878254; called by muse, mutect2, varscan2
- ADIPOR1 | c.71C>T p.T24M | Missense Mutation (SNP) | VAF 109/527 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as rs369139073; called by muse, mutect2, varscan2
- AGAP1 | c.1727G>A p.R576Q (on ENST00000304032 / NM_001037131.3; = p.R523Q on NM_014914.5) | Missense Mutation (SNP) | VAF 142/402 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs971441146; called by muse, mutect2, varscan2
- AHCTF1 | c.2911-1G>T p.X971_splice (on ENST00000366508; = p.X945_splice on NM_015446.5) | Splice Site (SNP) | VAF 54/200 reads (27%) | catalogued as COSV100404178; called by muse, mutect2, varscan2
- AHCYL2 | c.1565G>A p.R522H | Missense Mutation (SNP) | VAF 108/335 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs766038729, COSV61491254; called by muse, mutect2, varscan2
- AHNAK | c.2282G>T p.G761V | Missense Mutation (SNP) | VAF 224/522 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs754327408; called by muse, mutect2, varscan2
- AKAP12 | c.3479del p.P1160Lfs*18 | Frame Shift Del (DEL) | VAF 113/323 reads (35%) | catalogued as COSV53580835; called by mutect2, pindel, varscan2
- ALCAM | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 73/176 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV60253542; called by muse, mutect2, varscan2
- ANAPC11 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 130/390 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752711149; called by muse, mutect2, varscan2
- ANK2 | c.8025del p.G2676Vfs*11 | Frame Shift Del (DEL) | VAF 132/449 reads (29%) | catalogued as rs1564030096, COSV52170383; called by mutect2, varscan2
- ANO8 | c.1087del p.L363Cfs*24 | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | catalogued as COSV50178856; called by mutect2, pindel, varscan2
- ANO8 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 43/317 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); catalogued as COSV99344161; called by muse, mutect2, varscan2
- AP2A2 | c.170del p.K57Sfs*24 | Frame Shift Del (DEL) | VAF 48/111 reads (43%) | catalogued as rs753029866; called by mutect2, varscan2
- APC | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs767741687, COSV57361006; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP28 | c.904del p.R302Efs*16 (on ENST00000383472 / NM_001366230.1; = p.R143Efs*16 on NM_001010000.3) | Frame Shift Del (DEL) | VAF 65/209 reads (31%) | catalogued as COSV51632340; called by mutect2, pindel, varscan2
- ARHGAP32 | c.4886G>A p.R1629H (on ENST00000310343 / NM_001378025.1; = p.R1280H on NM_014715.4) | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0.011); catalogued as rs1363607024; called by muse, mutect2, varscan2
- ARHGAP33 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 63/227 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1363584324, COSV99140221; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 82/226 reads (36%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARSI | c.1631G>A p.R544H | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.154); catalogued as rs763136370, COSV60817209; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASCL4 | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.11); catalogued as rs746756373, COSV100661143; called by muse, mutect2
- ATP10D | c.1848del p.L617Cfs*41 | Frame Shift Del (DEL) | VAF 17/47 reads (36%) | catalogued as rs764067652, COSV56705401; called by mutect2, pindel, varscan2
- ATP4A | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 141/478 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as rs769990049, COSV52866484, COSV99382287; called by muse, mutect2, varscan2
- ATR | c.5440del p.R1814Efs*10 | Frame Shift Del (DEL) | VAF 67/239 reads (28%) | catalogued as rs1268253442; called by mutect2, pindel, varscan2
- ATXN2L | c.2997del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 16/41 reads (39%) | catalogued as rs1288664341; called by mutect2, pindel
- AXDND1 | c.2776G>A p.E926K | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV62640575; called by muse, mutect2, varscan2
- AZU1 | c.483del p.R162Vfs*11 | Frame Shift Del (DEL) | VAF 85/239 reads (36%) | catalogued as rs772652509, COSV99297150; called by mutect2, pindel, varscan2
- B3GALNT2 | c.1183G>A p.G395R | Missense Mutation (SNP) | VAF 50/229 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs929108412, COSV100782853; called by muse, mutect2, varscan2
- BAIAP3 | c.1928C>T p.A643V | Missense Mutation (SNP) | VAF 110/249 reads (44%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs199973519, COSV99136344; called by muse, mutect2, varscan2
- BCHE | c.373G>A p.V125I | Missense Mutation (SNP) | VAF 77/219 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.178); catalogued as rs1230054763, COSV52256733; called by muse, mutect2, varscan2
- BCL6B | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 71/160 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs578215266, COSV53426078, COSV53427535; called by muse, mutect2, varscan2
- BNC2 | c.159_162del p.E55Hfs*13 | Frame Shift Del (DEL) | VAF 256/646 reads (40%) | catalogued as rs1391476398; called by mutect2, pindel, varscan2
- BOC | c.2420G>A p.C807Y | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56347703, COSV56359507; called by muse, mutect2, varscan2
- BRD4 | c.2336del p.P779Rfs*15 | Frame Shift Del (DEL) | VAF 57/173 reads (33%) | catalogued as COSV54583043; called by mutect2, pindel, varscan2
- C14orf39 | c.1762del p.*588Efs*16 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | catalogued as rs780875081; called by mutect2, varscan2
- C2CD2L | c.1892G>A p.R631H | Missense Mutation (SNP) | VAF 84/187 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs561253373; called by muse, mutect2, varscan2
- C3 | c.299A>G p.K100R | Missense Mutation (SNP) | VAF 81/208 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV55575801; called by muse, mutect2, varscan2
- CACNA1A | c.2545G>A p.V849M | Missense Mutation (SNP) | VAF 251/673 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1168020406, COSV64202185; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1B | c.4739G>A p.R1580H | Missense Mutation (SNP) | VAF 125/310 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377465019; called by muse, mutect2, varscan2
- CAPZA3 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1192883904; called by muse, mutect2, varscan2
- CASP8AP2 | c.3842C>T p.A1281V | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs1217133573; called by muse, mutect2, varscan2
- CCDC105 | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 81/175 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.15); catalogued as rs760693691, COSV52963515; called by muse, mutect2, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 50/124 reads (40%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC86 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 72/203 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs573397831; called by muse, mutect2, varscan2
- CCNJL | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 192/450 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.096); catalogued as rs747122783; called by muse, varscan2
- CCNJL | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 96/246 reads (39%) | catalogued as rs773605574; called by muse, varscan2
- CCT6B | c.725+1G>A p.X242_splice | Splice Site (SNP) | VAF 40/80 reads (50%) | catalogued as rs376851436, COSV58489082; called by muse, mutect2, varscan2
- CDC42BPG | c.4293del p.F1431Lfs*16 | Frame Shift Del (DEL) | VAF 104/344 reads (30%) | catalogued as rs570535506; called by pindel, varscan2
- CDCA7 | c.910C>T p.R304C (on ENST00000347703 / NM_145810.3; = p.R383C on NM_031942.5) | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60720386; called by muse, mutect2, varscan2
- CDH23 | c.1823G>A p.S608N | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs774745111; called by muse, mutect2, varscan2
- CDH6 | c.1926del p.E643Sfs*3 | Frame Shift Del (DEL) | VAF 30/137 reads (22%) | catalogued as rs1561075636; called by mutect2, pindel, varscan2
- CDHR5 | c.2365G>A p.E789K (on ENST00000358353 / NM_001171968.2; = p.E795K on NM_021924.5) | Missense Mutation (SNP) | VAF 209/551 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.056); catalogued as rs371913447; called by muse, mutect2, varscan2
- CEACAM16 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs771309051; called by muse, mutect2, varscan2
- CEBPD | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 57/226 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as rs1226589852; called by muse, mutect2, varscan2
- CELSR3 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs1031937400; called by muse, mutect2, varscan2
- CEMIP | c.2531A>G p.N844S | Missense Mutation (SNP) | VAF 165/785 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54991977; called by muse, mutect2, varscan2
- CFAP44 | c.2218C>T p.P740S | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs368620724; called by muse, varscan2
- CHD4 | c.3446G>A p.R1149Q (on ENST00000357008 / NM_001363606.2; = p.R1162Q on NM_001273.5) | Missense Mutation (SNP) | VAF 84/212 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58903721; called by muse, mutect2, varscan2
- CHRD | c.878del p.P293Hfs*5 | Frame Shift Del (DEL) | VAF 47/186 reads (25%) | catalogued as COSV99200397; called by mutect2, pindel, varscan2
- CHRNA5 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs200127699, COSV55138194, COSV55139165; called by muse, mutect2
- CKAP2 | c.283G>A p.V95M (on ENST00000378037 / NM_001098525.2; = p.V94M on NM_018204.5) | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1566098525; called by muse, mutect2, varscan2
- CKLF | c.447del p.E150Kfs*? (on ENST00000264001 / NM_016951.4; = p.E65Kfs*? on NM_016326.3) | Frame Shift Del (DEL) | VAF 86/273 reads (32%) | catalogued as rs754415052; called by mutect2, varscan2
- CLEC16A | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs367927027; called by muse, mutect2, varscan2
- CLSPN | c.1757G>A p.S586N | Missense Mutation (SNP) | VAF 149/407 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs1557515939; called by muse, mutect2, varscan2
- COL20A1 | c.2582del p.G861Afs*23 | Frame Shift Del (DEL) | VAF 63/220 reads (29%) | catalogued as COSV100490176; called by mutect2, pindel, varscan2
- COL24A1 | c.3807del p.G1270Efs*68 | Frame Shift Del (DEL) | VAF 86/244 reads (35%) | catalogued as rs751232308; called by mutect2, pindel, varscan2
- COL27A1 | c.5059G>A p.A1687T | Missense Mutation (SNP) | VAF 96/225 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs755869669, COSV61930209; called by muse, mutect2, varscan2
- COX6B1 | c.-11-8G>A | Splice Region (SNP) | VAF 28/528 reads (5%) | catalogued as rs200312775; ClinVar: likely benign; called by muse, mutect2
- CPNE5 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 96/255 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.117); catalogued as rs1218572824, COSV55196220; called by muse, varscan2
- CPNE5 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 80/178 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372874067; called by muse, varscan2
- CPSF7 | c.1295G>A p.R432Q (on ENST00000394888 / NM_001136040.4; = p.R475Q on NM_024811.4) | Missense Mutation (SNP) | VAF 73/165 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs775930483, COSV100467717; called by muse, mutect2, varscan2
- CPT1A | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 215/586 reads (37%) | catalogued as rs767241290; called by muse, mutect2, varscan2
- CRYBG2 | c.1178del p.K393Rfs*16 | Frame Shift Del (DEL) | VAF 15/36 reads (42%) | catalogued as rs747248693; called by mutect2, varscan2
- CSMD1 | c.7009G>T p.G2337W (on ENST00000520002; = p.G2336W on NM_033225.6) | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866721621; called by muse, mutect2, varscan2
- CTNNA3 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 153/489 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs139378888; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNB1 | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 386/979 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.077); catalogued as rs764576683, COSV62692581; called by muse, mutect2, varscan2
- CWC27 | c.973C>T p.R325W | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs763896931, COSV66887071; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DAPL1 | c.127del p.T43Qfs*21 | Frame Shift Del (DEL) | VAF 29/94 reads (31%) | catalogued as rs763165810; called by mutect2, pindel, varscan2
- DCLK3 | c.1037G>A p.G346D | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs1240940774; called by muse, mutect2, varscan2
- DDX3X | c.1421G>A p.R474H (on ENST00000399959; = p.R475H on NM_001356.5) | Missense Mutation (SNP) | VAF 77/188 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV67863186; called by muse, mutect2, varscan2
- DENND2C | c.387_389del p.E129del | In Frame Del (DEL) | VAF 60/204 reads (29%) | catalogued as rs774959242; called by pindel, varscan2
- DGKA | c.2176del p.R726Afs*9 | Frame Shift Del (DEL) | VAF 92/255 reads (36%) | catalogued as COSV59384233; called by mutect2, pindel, varscan2
- DGLUCY | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 100/256 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs759389819; called by muse, mutect2, varscan2
- DHPS | c.758C>A p.P253Q | Missense Mutation (SNP) | VAF 90/266 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV99269620; called by muse, mutect2, varscan2
- DIDO1 | c.6101del p.P2034Rfs*240 | Frame Shift Del (DEL) | VAF 9/63 reads (14%) | catalogued as COSV56634983; called by mutect2, pindel, varscan2
- DIP2C | c.3790G>T p.V1264L | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.276); catalogued as COSV55151002; called by muse, mutect2, varscan2
- DLC1 | c.2057C>T p.A686V (on ENST00000276297 / NM_001348081.2; = p.A249V on NM_006094.5) | Missense Mutation (SNP) | VAF 73/199 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs142931995; called by muse, mutect2, varscan2
- DLG3 | c.1633C>T p.Q545* (on ENST00000374360 / NM_021120.4; = p.Q208* on NM_020730.3) | Nonsense Mutation (SNP) | VAF 184/446 reads (41%) | catalogued as COSV52085052; called by muse, mutect2, varscan2
- DMWD | c.1406C>T p.T469M | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.613); catalogued as rs779740321; called by muse, mutect2, varscan2
- DNAH12 | c.276del p.G93Dfs*7 | Frame Shift Del (DEL) | VAF 43/126 reads (34%) | catalogued as rs751671358; called by mutect2, varscan2
- DNAH2 | c.11786T>C p.I3929T | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs777514853; called by muse, mutect2, varscan2
- DNAH6 | c.911del p.N304Ifs*16 | Frame Shift Del (DEL) | VAF 24/73 reads (33%) | catalogued as rs763637561; called by mutect2, pindel, varscan2
- DNAH8 | c.4418del p.N1473Ifs*15 | Frame Shift Del (DEL) | VAF 42/102 reads (41%) | catalogued as rs778628413, COSV59486260; called by mutect2, varscan2
- DOK1 | c.245dup p.E83* | Frame Shift Ins (INS) | VAF 167/478 reads (35%) | catalogued as rs750803751; called by mutect2, varscan2
- DSCAML1 | c.5048G>A p.R1683Q (on ENST00000321322; = p.R1623Q on NM_020693.4) | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs756425038; called by muse, mutect2, varscan2
- DUS2 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 81/186 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768614400; called by muse, mutect2, varscan2
- DZIP1L | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 132/329 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs762332715; called by muse, mutect2, varscan2
- ELFN1 | c.1819G>A p.A607T | Missense Mutation (SNP) | VAF 143/376 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs777903379, COSV70036773; called by muse, mutect2, varscan2
- ENOPH1 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs759534376; called by muse, mutect2, varscan2
- EPHA2 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 225/585 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.53); catalogued as COSV100626213; called by muse, mutect2, varscan2
- EPHA8 | c.2287G>A p.A763T | Missense Mutation (SNP) | VAF 240/668 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs149930866; called by muse, mutect2, varscan2
- ERBB2 | c.1361G>A p.G454E | Missense Mutation (SNP) | VAF 14/448 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1410783126; called by muse, mutect2
- ERI2 | c.1766G>A p.S589N | Missense Mutation (SNP) | VAF 99/324 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.01); catalogued as rs775766126; called by muse, mutect2, varscan2
- ERICH3 | c.3506del p.N1169Tfs*2 | Frame Shift Del (DEL) | VAF 45/149 reads (30%) | catalogued as COSV58619446; called by mutect2, pindel, varscan2
- ERMAP | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 171/406 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs563298024, COSV60273887; called by muse, mutect2, varscan2
- ESPNL | c.2264C>T p.T755M | Missense Mutation (SNP) | VAF 108/300 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs1000805144, COSV58036366; called by muse, mutect2, varscan2
- EXOC3 | c.77T>C p.L26P | Missense Mutation (SNP) | VAF 99/214 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1402255797; called by muse, mutect2, varscan2
- FADS3 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.477); catalogued as rs377115399, COSV53877446; called by muse, mutect2, varscan2
- FAM234B | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs148007869; called by muse, mutect2, varscan2
- FAM9A | c.477del p.K159Nfs*3 | Frame Shift Del (DEL) | VAF 107/139 reads (77%) | catalogued as rs748967872; called by mutect2, varscan2
- FARP2 | c.2743C>T p.R915W | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1449861556; called by muse, mutect2, varscan2
- FAT3 | c.4902G>A p.M1634I | Missense Mutation (SNP) | VAF 93/212 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV99963809; called by muse, mutect2, varscan2
- FBXW9 | c.452G>A p.R151H (on ENST00000587955; = p.R161H on NM_032301.3) | Missense Mutation (SNP) | VAF 65/298 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as rs375478011; called by muse, mutect2, varscan2
- FCGBP | c.1453G>A p.G485S | Missense Mutation (SNP) | VAF 100/294 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs1475266054; called by muse, mutect2
- FGD3 | c.367del p.Q123Rfs*51 | Frame Shift Del (DEL) | VAF 57/176 reads (32%) | catalogued as rs777351004, COSV100490512; called by mutect2, pindel, varscan2
- FGF8 | c.628G>A p.E210K (on ENST00000344255 / NM_033164.4; = p.E192K on NM_006119.6) | Missense Mutation (SNP) | VAF 151/386 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.893); catalogued as rs1370886145; called by muse, mutect2, varscan2
- FGFR2 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 146/418 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs781714766, COSV60641778; called by muse, mutect2, varscan2
- FKRP | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 101/262 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs754088436; called by muse, mutect2, varscan2
- FLT3LG | c.351del p.S118Afs*24 | Frame Shift Del (DEL) | VAF 48/64 reads (75%) | catalogued as rs769482947; called by mutect2, varscan2
- FMNL3 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.536); catalogued as rs754025129; called by muse, mutect2, varscan2
- FOXD4L1 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 204/801 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs768136068; called by muse, mutect2, varscan2
- FREM2 | c.6958G>A p.V2320M | Missense Mutation (SNP) | VAF 165/359 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs1268483221, COSV54833272; called by muse, varscan2
- FRZB | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1442023364; called by muse, mutect2
- FZD2 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 24/406 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs770035472, COSV59528209, COSV59528679; called by muse, mutect2
- GABRB1 | c.78C>T p.H26= | Splice Region (SNP) | VAF 85/237 reads (36%) | catalogued as COSV99783620; called by muse, mutect2, varscan2
- GARRE1 | c.3184C>T p.R1062C | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); catalogued as rs530232322; called by muse, mutect2, varscan2
- GATAD2B | c.1717C>T p.R573C | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64086158; called by muse, mutect2, varscan2
- GBE1 | c.1079C>T p.T360M | Missense Mutation (SNP) | VAF 38/386 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs745405800; called by muse, mutect2, varscan2
- GDA | c.579-1G>T p.X193_splice | Splice Site (SNP) | VAF 53/145 reads (37%) | catalogued as COSV52998111; called by muse, mutect2, varscan2
- GFPT2 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 116/280 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs757899837, COSV53806552; called by muse, mutect2, varscan2
- GLA | c.1166C>A p.P389H | Missense Mutation (SNP) | VAF 143/396 reads (36%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.996); catalogued as CM078393, CM138906; called by muse, mutect2, varscan2
- GLDC | c.1381C>T p.R461W | Missense Mutation (SNP) | VAF 163/432 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761957837, CM1510120, COSV58678266; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPHN | c.949C>T p.R317C (on ENST00000315266 / NM_001377519.1; = p.R350C on NM_020806.5) | Missense Mutation (SNP) | VAF 111/353 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59488842; called by muse, mutect2, varscan2
- GPR142 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as rs367783578; called by muse, mutect2
- GPR143 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 210/504 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.416); catalogued as COSV101102214; called by muse, mutect2, varscan2
- GSE1 | c.366dup p.V123Rfs*17 | Frame Shift Ins (INS) | VAF 20/62 reads (32%) | catalogued as rs754199513; called by mutect2, varscan2
- GTF2IRD2B | c.1793G>A p.R598H | Missense Mutation (SNP) | VAF 156/467 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.63); catalogued as rs200522526, COSV100441347; called by muse, mutect2, varscan2
- H1-8 | c.161del p.P54Rfs*44 | Frame Shift Del (DEL) | VAF 47/212 reads (22%) | catalogued as rs768737255; called by mutect2, pindel, varscan2
- HMCN2 | c.12524C>T p.T4175M | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.51); catalogued as rs960747751; called by muse, mutect2, varscan2
- HMGCS1 | c.1438G>A p.G480R | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs1397860513; called by muse, mutect2, varscan2
- HMGXB3 | c.3887G>A p.R1296Q (on ENST00000613459; = p.R1050Q on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 134/310 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745836949; called by muse, mutect2, varscan2
- HMX3 | c.68del p.P23Hfs*100 | Frame Shift Del (DEL) | VAF 10/41 reads (24%) | catalogued as rs779589617; called by mutect2, varscan2
- HOXA11 | c.895del p.I299Lfs*30 | Frame Shift Del (DEL) | VAF 206/621 reads (33%) | catalogued as rs777829525; called by mutect2, varscan2
- HRG | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 101/284 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs370234178; called by muse, mutect2, varscan2
- HTATSF1 | c.1368del p.E457Rfs*35 | Frame Shift Del (DEL) | VAF 56/204 reads (27%) | catalogued as COSV54481935; called by mutect2, pindel, varscan2
- ICE1 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201580742; called by muse, mutect2, varscan2
- IGF1R | c.2155C>T p.R719C | Missense Mutation (SNP) | VAF 152/417 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs757536805; called by muse, mutect2, varscan2
- IGFBP5 | c.120dup p.S41Qfs*78 | Frame Shift Ins (INS) | VAF 38/78 reads (49%) | catalogued as rs748087175; called by mutect2, varscan2
- IGHV4-39 | c.24G>A p.M8I | Missense Mutation (SNP) | VAF 15/374 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as rs778973963; called by muse, mutect2
- IGLON5 | c.750G>A p.W250* | Nonsense Mutation (SNP) | VAF 69/174 reads (40%) | catalogued as rs1423065925; called by muse, mutect2, varscan2
- IGSF22 | c.2306C>T p.T769I (on ENST00000319338; = p.T870I on NM_173588.4) | Missense Mutation (SNP) | VAF 68/205 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs372092174; called by muse, mutect2, varscan2
- IGSF9B | c.2837G>A p.R946Q | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as rs756219238, COSV100316869; called by muse, mutect2, varscan2
- IL17REL | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 70/205 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.084); catalogued as rs866785241; called by muse, mutect2, varscan2
- ILVBL | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as rs370758360; called by muse, mutect2, varscan2
- IPO11 | c.2419del p.S807Lfs*22 | Frame Shift Del (DEL) | VAF 24/128 reads (19%) | catalogued as rs1561359523; called by mutect2, varscan2
- IPO8 | c.167-1G>A p.X56_splice | Splice Site (SNP) | VAF 47/130 reads (36%) | catalogued as COSV99805501; called by muse, mutect2, varscan2
- IQSEC3 | c.2353G>A p.A785T (on ENST00000538872 / NM_001170738.2; = p.A482T on NM_015232.1) | Missense Mutation (SNP) | VAF 79/259 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1161199661, COSV100407231; called by muse, mutect2, varscan2
- ITPR2 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1159482369, COSV67270866; called by muse, mutect2, varscan2
- ITPRIPL2 | c.861del p.T288Pfs*62 | Frame Shift Del (DEL) | VAF 90/263 reads (34%) | catalogued as rs761512894; called by mutect2, pindel, varscan2
- JAK3 | c.2084G>A p.C695Y | Missense Mutation (SNP) | VAF 84/211 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1203686982, COSV104438104; called by muse, mutect2, varscan2
- KANK1 | c.1624G>A p.V542M | Missense Mutation (SNP) | VAF 127/325 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.242); catalogued as rs146416309; called by muse, mutect2, varscan2
- KDM4D | c.278del p.K93Rfs*4 | Frame Shift Del (DEL) | VAF 50/155 reads (32%) | catalogued as rs142280183; called by mutect2, varscan2
- KIAA0825 | c.3032C>T p.A1011V | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.096); catalogued as rs1351833883; called by muse, mutect2, varscan2
- KIAA1109 | c.6283C>T p.R2095C | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs528587230, COSV52667344; called by muse, mutect2, varscan2
- KIF26B | c.5116G>A p.A1706T | Missense Mutation (SNP) | VAF 108/335 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs1454001800; called by muse, mutect2, varscan2
- KLHL10 | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1302156953, COSV53173028; called by muse, mutect2, varscan2
- KLHL35 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.321); catalogued as COSV100888776; called by muse, mutect2, varscan2
- KLK6 | c.718dup p.T240Nfs*45 | Frame Shift Ins (INS) | VAF 62/187 reads (33%) | catalogued as rs750767249; called by mutect2, pindel, varscan2
- KNSTRN | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV51109762; called by muse, mutect2
- KRT6B | c.395del p.P132Lfs*14 | Frame Shift Del (DEL) | VAF 213/1128 reads (19%) | catalogued as rs772129177; called by mutect2, pindel, varscan2
- KRT80 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 144/383 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs564779835; called by muse, mutect2, varscan2
- KRTAP10-9 | c.634C>T p.Q212* | Nonsense Mutation (SNP) | VAF 195/741 reads (26%) | catalogued as COSV59975686; called by muse, mutect2, varscan2
- L3MBTL3 | c.230del p.P77Rfs*32 | Frame Shift Del (DEL) | VAF 56/189 reads (30%) | catalogued as COSV62384647; called by mutect2, pindel, varscan2
- LARP4 | c.1843C>T p.R615* | Nonsense Mutation (SNP) | VAF 43/108 reads (40%) | catalogued as COSV53324578; called by muse, mutect2
- LATS2 | c.1888G>T p.E630* | Nonsense Mutation (SNP) | VAF 36/104 reads (35%) | catalogued as COSV101231712; called by muse, mutect2, varscan2
- LETM2 | c.1193C>T p.P398L (on ENST00000379957 / NM_001286819.2; = p.P303L on NM_144652.3) | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs1313584716; called by muse, mutect2, varscan2
- LMOD1 | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 157/537 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs763440069, COSV66172684; called by muse, mutect2, varscan2
- LRIF1 | c.2099A>G p.H700R | Missense Mutation (SNP) | VAF 126/318 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs778203277; called by muse, mutect2, varscan2
- LRIG2 | c.2855A>C p.Q952P | Missense Mutation (SNP) | VAF 126/366 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1210989908; called by muse, mutect2, varscan2
- LRP1 | c.4039G>T p.E1347* | Nonsense Mutation (SNP) | VAF 99/514 reads (19%) | catalogued as rs1555184506, COSV54518660; called by muse, mutect2, varscan2
- LRP12 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 53/216 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as rs758111725, COSV52625897; called by muse, mutect2, varscan2
- LRRIQ1 | c.4624del p.I1542Ffs*17 | Frame Shift Del (DEL) | VAF 32/104 reads (31%) | catalogued as rs745692987; called by mutect2, varscan2
- LSG1 | c.1595C>T p.A532V | Missense Mutation (SNP) | VAF 81/254 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs763071707, COSV54569510; called by muse, mutect2, varscan2
- LTB4R2 | c.1150G>A p.G384S (on ENST00000528054; = p.G353S on NM_019839.5) | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs756992579, COSV51864542; called by muse, mutect2, varscan2
- LTK | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 100/282 reads (35%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.358); catalogued as rs140090710; called by muse, mutect2, varscan2
- MAGEC1 | c.2240G>C p.C747S | Missense Mutation (SNP) | VAF 78/182 reads (43%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.227); catalogued as rs139916073; called by muse, mutect2, varscan2
- MAP3K21 | c.1674G>A p.Q558= | Splice Region (SNP) | VAF 83/284 reads (29%) | catalogued as rs547287571; called by muse, mutect2, varscan2
- MAPK7 | c.1763C>T p.A588V | Missense Mutation (SNP) | VAF 97/257 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1212748750; called by muse, mutect2, varscan2
- MARF1 | c.4333C>A p.H1445N | Missense Mutation (SNP) | VAF 110/348 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.341); catalogued as rs777933126; called by muse, mutect2, varscan2
- MARK2 | c.2071C>T p.R691C (on ENST00000402010 / NM_001039469.2; = p.R627C on NM_004954.5) | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99041571; called by muse, mutect2, varscan2
- MARK4 | c.1252C>T p.R418C | Missense Mutation (SNP) | VAF 71/178 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780763668, COSV53464983, COSV99489105; called by muse, mutect2, varscan2
- MAST2 | c.4904C>T p.S1635L | Missense Mutation (SNP) | VAF 27/312 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs369652939; called by muse, mutect2
- MBD6 | c.1984del p.L662Yfs*13 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | catalogued as rs1163818902; called by mutect2, pindel, varscan2
- MED14 | c.3631C>A p.L1211I | Missense Mutation (SNP) | VAF 103/315 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV61357419; called by muse, mutect2, varscan2
- MEN1 | c.670-5del | Splice Region (DEL) | VAF 75/356 reads (21%) | catalogued as rs772016629; ClinVar: benign / likely benign; called by mutect2, varscan2
- MESD | c.632del p.K211Rfs*6 | Frame Shift Del (DEL) | VAF 90/228 reads (39%) | catalogued as rs745891632; called by mutect2, varscan2
- MESP2 | c.564G>T p.Q188H | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs1292705592; called by muse, mutect2, varscan2
- METTL2A | c.578A>G p.N193S | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as rs747253879; called by muse, mutect2, varscan2
- MIOS | c.1202G>T p.R401M | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV100402897; called by muse, mutect2, varscan2
- MMRN1 | c.3647del p.P1216Lfs*17 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | catalogued as COSV53334580, COSV53343010; called by mutect2, pindel, varscan2
- MOCOS | c.1898G>A p.R633Q | Missense Mutation (SNP) | VAF 180/324 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as rs766703333, COSV54345558; called by muse, mutect2, varscan2
- MPP6 | c.917del p.K306Rfs*4 | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | catalogued as rs757450051; ClinVar: not provided; called by mutect2, varscan2
- MRGPRG | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs1286401856; called by muse, mutect2, varscan2
- MRS2 | c.1327C>T p.R443C | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as rs776046884, COSV51234857, COSV99218637; called by muse, varscan2
- MTMR12 | c.1853G>A p.S618N | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs762460927; called by muse, mutect2, varscan2
- MUC12 | c.14993G>A p.S4998N (on ENST00000379442; = p.S4855N on NM_001164462.1) | Missense Mutation (SNP) | VAF 115/320 reads (36%) | SIFT deleterious (0); catalogued as rs1267145306; called by muse, mutect2, varscan2
- MUC16 | c.31412del p.R10471Kfs*9 | Frame Shift Del (DEL) | VAF 19/61 reads (31%) | catalogued as rs1243024568, COSV67492204; called by mutect2, pindel, varscan2
- MUC19 | c.461del p.K154Sfs*87 | Frame Shift Del (DEL) | VAF 40/112 reads (36%) | catalogued as rs537060918; called by mutect2, varscan2
- MUC4 | c.11921G>A p.R3974H | Missense Mutation (SNP) | VAF 225/341 reads (66%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.448); catalogued as COSV57767737; called by muse, mutect2, varscan2
- MVD | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 116/316 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1281597517; called by muse, mutect2, varscan2
- MYOC | c.425A>G p.Y142C | Missense Mutation (SNP) | VAF 196/701 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs576184926; called by muse, mutect2, varscan2
- MYOF | c.4339-1G>T p.X1447_splice | Splice Site (SNP) | VAF 7/160 reads (4%) | catalogued as COSV63709370; called by muse, mutect2
- MYOM2 | c.1827C>A p.T609= | Splice Region (SNP) | VAF 46/107 reads (43%) | catalogued as COSV100039002; called by muse, mutect2, varscan2
- NACC2 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as rs746624435; called by muse, mutect2, varscan2
- NAPG | c.666-1G>A p.X222_splice | Splice Site (SNP) | VAF 46/115 reads (40%) | catalogued as rs1186333569, COSV59797326; called by muse, mutect2, varscan2
- NBEAL2 | c.6517G>A p.V2173M | Missense Mutation (SNP) | VAF 80/207 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as rs768276685, COSV99438120; called by muse, mutect2, varscan2
- NCKAP5L | c.497G>A p.G166D | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.065); catalogued as rs756375507; called by muse, mutect2, varscan2
- NDE1 | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 78/196 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as rs749543506; called by muse, mutect2, varscan2
- NFRKB | c.2681C>T p.T894M (on ENST00000446488 / NM_001143835.2; = p.T919M on NM_006165.3) | Missense Mutation (SNP) | VAF 94/267 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.113); catalogued as rs746347631; called by muse, mutect2, varscan2
- NLRP6 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763915009; called by muse, mutect2, varscan2
- NOL8 | c.1033G>A p.V345I | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs750294867; called by muse, mutect2, varscan2
- NOTCH4 | c.5672dup p.G1892Rfs*24 | Frame Shift Ins (INS) | VAF 62/182 reads (34%) | catalogued as rs777647776; called by mutect2, varscan2
- NUAK2 | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as rs532473739; called by muse, mutect2, varscan2
- NUDT1 | c.298G>A p.E100K (on ENST00000397048 / NM_198952.1; = p.E77K on NM_002452.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/630 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.183); catalogued as rs374195109; called by muse, mutect2
- NUP188 | c.3460C>T p.R1154C | Missense Mutation (SNP) | VAF 89/264 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs200827758; called by muse, mutect2, varscan2
- OBSCN | c.20977del p.A6993Pfs*79 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | catalogued as rs762005098; called by mutect2, pindel, varscan2
- OR2M4 | c.174del p.M59Cfs*23 | Frame Shift Del (DEL) | VAF 37/172 reads (22%) | catalogued as COSV60708101; called by mutect2, pindel, varscan2
- OR2W3 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 72/264 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs201306772, COSV64457516; called by muse, mutect2
- OR3A1 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 139/317 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372689671; called by muse, mutect2, varscan2
- OR4C6 | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 103/242 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.378); catalogued as rs763521348, COSV100051639, COSV58603342, COSV58603558; called by muse, mutect2, varscan2
- OR4K17 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 94/283 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100210735; called by muse, mutect2, varscan2
- OR4Q3 | c.692T>C p.L231P | Missense Mutation (SNP) | VAF 126/509 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59177765; called by muse, mutect2, varscan2
- OR5AU1 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 101/230 reads (44%) | SIFT tolerated (0.95); PolyPhen benign (0.241); catalogued as COSV58616334; called by muse, mutect2, varscan2
- OR6C68 | c.303dup p.A102Cfs*8 | Frame Shift Ins (INS) | VAF 38/124 reads (31%) | catalogued as rs1214120731; called by mutect2, pindel, varscan2
- OR6K6 | c.329T>C p.L110P (on ENST00000368144; = p.L86P on NM_001005184.1) | Missense Mutation (SNP) | VAF 45/195 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100933790; called by muse, mutect2, varscan2
- OR6P1 | c.96del p.F32Lfs*6 | Frame Shift Del (DEL) | VAF 98/361 reads (27%) | catalogued as rs201077183; called by mutect2, varscan2
- P2RY8 | c.370G>T p.G124W | Missense Mutation (SNP) | VAF 102/236 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101184020; called by muse, mutect2, varscan2
- PARD3B | c.1628G>A p.R543H | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748008390; called by muse, mutect2
- PATZ1 | c.2044A>G p.M682V | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs936275018; called by muse, mutect2, varscan2
- PCDH18 | c.2756C>T p.T919M | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs139751813, COSV61271520; called by muse, mutect2, varscan2
- PCDHB3 | c.846del p.H283Mfs*12 | Frame Shift Del (DEL) | VAF 63/193 reads (33%) | catalogued as rs781965023; called by mutect2, pindel, varscan2
- PCDHGA2 | c.2008G>A p.D670N | Missense Mutation (SNP) | VAF 305/743 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as rs755988520, COSV53985455; called by muse, mutect2, varscan2
- PCGF2 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 68/152 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as rs991646402; called by muse, mutect2, varscan2
- PCNX3 | c.1606A>G p.S536G | Missense Mutation (SNP) | VAF 209/544 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs935167914; called by muse, mutect2, varscan2
- PDCD11 | c.1144del p.A382Pfs*5 | Frame Shift Del (DEL) | VAF 101/359 reads (28%) | catalogued as COSV63934252; called by mutect2, pindel, varscan2
- PER2 | c.871A>G p.M291V | Missense Mutation (SNP) | VAF 247/647 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs777751360; called by muse, mutect2, varscan2
- PES1 | c.188C>T p.T63M | Missense Mutation (SNP) | VAF 74/242 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747963784; called by muse, mutect2, varscan2
- PHEX | c.847G>T p.E283* | Nonsense Mutation (SNP) | VAF 96/273 reads (35%) | catalogued as COSV65074828; called by muse, mutect2, varscan2
- PI15 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 74/193 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142164571, COSV52642166; called by muse, mutect2, varscan2
- PIDD1 | c.2218C>T p.R740W | Missense Mutation (SNP) | VAF 78/175 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs145373644, COSV100204135; called by muse, mutect2, varscan2
- PIK3R2 | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 132/336 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.036); catalogued as rs770051333; called by muse, mutect2, varscan2
- PITPNM2 | c.373G>A p.V125M | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760673439; called by muse, mutect2, varscan2
- PKN1 | c.1208G>A p.G403E | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs972532809; called by muse, mutect2, varscan2
- PLAAT4 | c.483del p.A162Rfs*56 | Frame Shift Del (DEL) | VAF 91/212 reads (43%) | catalogued as rs745860467; called by mutect2, varscan2
- PLEC | c.11839G>A p.V3947M (on ENST00000322810 / NM_201380.4; = p.V3837M on NM_000445.5) | Missense Mutation (SNP) | VAF 105/262 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs781838084, COSV59638641; called by muse, mutect2, varscan2
- PLPP5 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 103/258 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs751401210; called by muse, mutect2, varscan2
- PLXNA1 | c.4869C>T p.Y1623= | Splice Region (SNP) | VAF 135/298 reads (45%) | catalogued as rs774909770, COSV52533071; called by muse, mutect2, varscan2
- PLXNC1 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.033); catalogued as rs576172182; called by muse, mutect2, varscan2
- PNPLA6 | c.1850G>A p.R617H (on ENST00000414982 / NM_001166111.2; = p.R569H on NM_006702.5) | Missense Mutation (SNP) | VAF 156/460 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV55376354; called by muse, mutect2, varscan2
- POLD3 | c.861del p.A288Qfs*17 | Frame Shift Del (DEL) | VAF 92/288 reads (32%) | catalogued as rs1565122953; called by mutect2, pindel, varscan2
- POTEI | c.2645G>A p.G882E | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1267232336; called by mutect2, varscan2
- POTEJ | c.2534G>A p.G845E | Missense Mutation (SNP) | VAF 38/322 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs564871504, COSV101284601; called by mutect2, varscan2
- PPP2R2C | c.1336A>G p.M446V | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV100160357; called by muse, mutect2
- PRG4 | c.3497G>A p.R1166Q | Missense Mutation (SNP) | VAF 164/606 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760696470, COSV63355685; called by muse, mutect2, varscan2
- PRPF40B | c.2537C>T p.T846M (on ENST00000380281; = p.T833M on NM_012272.3) | Missense Mutation (SNP) | VAF 140/350 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs770497698; called by muse, mutect2, varscan2
- PRPSAP2 | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs371840452; called by muse, mutect2, varscan2
- PRR12 | c.37del p.H13Tfs*66 (on ENST00000615927; = p.P408Hfs*62 on NM_020719.3) | Frame Shift Del (DEL) | VAF 51/128 reads (40%) | catalogued as rs763575972; called by mutect2, varscan2
- PSD | c.750del p.S251Afs*43 | Frame Shift Del (DEL) | VAF 25/86 reads (29%) | catalogued as rs761494960; called by mutect2, pindel, varscan2
- PSMG1 | c.393G>A p.S131= | Splice Region (SNP) | VAF 12/72 reads (17%) | catalogued as rs902396873, COSV59000310; called by muse, mutect2
- PTPN13 | c.4643T>C p.I1548T (on ENST00000411767 / NM_080683.3; = p.I1529T on NM_006264.3) | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755854008; called by muse, mutect2, varscan2
- R3HCC1L | c.284A>G p.D95G | Missense Mutation (SNP) | VAF 15/163 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.205); catalogued as rs754242171; called by muse, mutect2
- RADIL | c.808C>T p.R270W | Missense Mutation (SNP) | VAF 158/432 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs1250839417, COSV68200163; called by muse, mutect2, varscan2
- RAI1 | c.3446G>A p.R1149H | Missense Mutation (SNP) | VAF 18/348 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs772669262; called by muse, mutect2
- RAI2 | c.712G>A p.V238I | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.214); catalogued as rs1208705303, COSV58965561; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RANGAP1 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 28/378 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs959441695; called by muse, mutect2
- RAPGEF2 | c.3259del p.I1087Ffs*98 | Frame Shift Del (DEL) | VAF 40/90 reads (44%) | catalogued as rs760669443; called by mutect2, varscan2
- RAPGEF5 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 17/289 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.093); catalogued as rs921794246; called by muse, mutect2
- RBBP8 | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 56/301 reads (19%) | catalogued as rs771541058; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 40/121 reads (33%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RNF113B | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 165/409 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs151316967; called by muse, mutect2, varscan2
- RNF185 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 20/291 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.122); catalogued as rs1436069927, COSV56736567; called by muse, mutect2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 187/306 reads (61%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNMT | c.1180del p.T394Hfs*19 | Frame Shift Del (DEL) | VAF 6/65 reads (9%) | catalogued as rs1436309196; called by mutect2, pindel
- ROBO2 | c.3233dup p.V1079Sfs*22 | Frame Shift Ins (INS) | VAF 69/209 reads (33%) | catalogued as rs745519558; called by mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 98/249 reads (39%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RUBCN | c.830del p.P277Qfs*7 | Frame Shift Del (DEL) | VAF 69/360 reads (19%) | catalogued as rs745498865, COSV56364590; called by mutect2, pindel, varscan2
- SBNO2 | c.3994G>A p.A1332T | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.015); catalogued as rs1479262830; called by muse, mutect2, varscan2
- SBNO2 | c.2546C>T p.A849V | Missense Mutation (SNP) | VAF 131/341 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773576513; called by muse, mutect2, varscan2
- SCN5A | c.5139G>T p.W1713C (on ENST00000333535 / NM_198056.3; = p.W1712C on NM_000335.5) | Missense Mutation (SNP) | VAF 267/654 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61134679; called by muse, mutect2, varscan2
- SEC16A | c.3895G>A p.A1299T | Missense Mutation (SNP) | VAF 58/216 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs376172438, COSV51521071; called by muse, mutect2, varscan2
- SEC16B | c.1299del p.S434Vfs*29 | Frame Shift Del (DEL) | VAF 41/174 reads (24%) | catalogued as rs768388757; called by mutect2, pindel, varscan2
- SEC63 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 89/300 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs148837883; called by muse, mutect2, varscan2
- SEH1L | c.5T>C p.F2S | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.764); catalogued as rs1394599211; called by muse, mutect2
- SETD1B | c.2491G>A p.G831R | Missense Mutation (SNP) | VAF 22/397 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs1332887731; called by muse, mutect2
- SFSWAP | c.1156G>A p.G386R | Missense Mutation (SNP) | VAF 130/329 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763274532; called by muse, mutect2, varscan2
- SGK2 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 81/209 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as rs559824768, COSV58313047; called by muse, mutect2, varscan2
- SGSM1 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 114/295 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV68508538; called by muse, mutect2, varscan2
- SGSM3 | c.355A>G p.M119V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as rs1261349204; called by muse, mutect2, varscan2
- SGTA | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as rs374479958; called by muse, mutect2
- SH2D4B | c.974C>T p.A325V (on ENST00000646907; = p.A324V on NM_207372.2) | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs761271075; called by muse, mutect2, varscan2
- SH3GL1 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 235/631 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.067); catalogued as rs199700932; called by muse, mutect2, varscan2
- SHCBP1L | c.1017del p.K339Nfs*5 | Frame Shift Del (DEL) | VAF 58/229 reads (25%) | catalogued as rs756742767; called by mutect2, pindel, varscan2
- SHCBP1L | c.166C>A p.P56T | Missense Mutation (SNP) | VAF 172/555 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as COSV62353781; called by muse, mutect2, varscan2
- SKIL | c.908T>C p.F303S | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99378299; called by muse, mutect2, varscan2
- SLAMF1 | c.829del p.S277Afs*54 | Frame Shift Del (DEL) | VAF 80/390 reads (21%) | catalogued as rs751442558; called by mutect2, varscan2
- SLC17A7 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 112/264 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as rs1424382229; called by muse, mutect2, varscan2
- SLC19A2 | c.1224-4del | Splice Region (DEL) | VAF 68/298 reads (23%) | catalogued as rs750915834; called by mutect2, varscan2
- SLC22A13 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 75/279 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.393); catalogued as rs542608978; called by muse, mutect2, varscan2
- SLC25A24 | c.1249+2T>C p.X417_splice | Splice Site (SNP) | VAF 10/114 reads (9%) | catalogued as COSV99916197; called by muse, mutect2
- SLC34A2 | c.1585G>A p.A529T | Missense Mutation (SNP) | VAF 333/882 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs372824816; called by muse, mutect2, varscan2
- SLC36A1 | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 119/386 reads (31%) | catalogued as rs752846011; called by muse, mutect2, varscan2
- SLC6A13 | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 72/259 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.598); catalogued as rs772374178, COSV58259906; called by muse, mutect2, varscan2
- SLC6A3 | c.1762C>T p.R588* | Nonsense Mutation (SNP) | VAF 156/453 reads (34%) | catalogued as rs1333211743, COSV54368060; called by muse, mutect2, varscan2
- SLC7A10 | c.471del p.T158Pfs*12 | Frame Shift Del (DEL) | VAF 98/315 reads (31%) | catalogued as rs753589038, COSV53507811; called by mutect2, pindel, varscan2
- SLC7A13 | c.372del p.S126Afs*20 | Frame Shift Del (DEL) | VAF 103/290 reads (36%) | catalogued as COSV52536834; called by mutect2, pindel, varscan2
- SLC9C2 | c.1577G>C p.R526P | Missense Mutation (SNP) | VAF 158/323 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.216); catalogued as rs775523749, COSV100876690, COSV100876800; called by muse, mutect2, varscan2
- SLFNL1 | c.11T>C p.M4T | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); catalogued as rs375276089; called by muse, mutect2, varscan2
- SLITRK1 | c.1502T>C p.L501P | Missense Mutation (SNP) | VAF 153/443 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV65676905; called by muse, mutect2, varscan2
- SMYD3 | c.877del p.I293Lfs*4 (on ENST00000490107 / NM_001375962.1; = p.I234Lfs*4 on NM_022743.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 81/372 reads (22%) | catalogued as rs1558435001; called by mutect2, pindel, varscan2
- SNCAIP | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 121/336 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs755797209, COSV99750120; called by muse, mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 56/177 reads (32%) | catalogued as rs768873484; called by mutect2, varscan2
- SOX11 | c.905C>T p.T302I | Missense Mutation (SNP) | VAF 99/248 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs1267359699; called by muse, mutect2, varscan2
- SPDYA | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 62/151 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs771698422, COSV61856457; called by muse, mutect2, varscan2
- SPIRE2 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142759329; called by muse, mutect2, varscan2
- SPTB | c.3649A>G p.M1217V | Missense Mutation (SNP) | VAF 202/547 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.18); catalogued as rs146846892; called by muse, mutect2, varscan2
- SRCAP | c.6536del p.K2179Rfs*128 | Frame Shift Del (DEL) | VAF 61/169 reads (36%) | catalogued as COSV52675361; called by mutect2, pindel, varscan2
- SRP19 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 102/319 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.514); catalogued as rs761772910; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.336G>T p.Q112H | Missense Mutation (SNP) | VAF 125/263 reads (48%) | PolyPhen benign (0.201); catalogued as rs1439404108; called by muse, mutect2, varscan2
- STAP2 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 133/387 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55699249; called by muse, mutect2, varscan2
- STK38L | c.1192A>G p.I398V | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as rs1007662676; called by muse, mutect2, varscan2
- SV2B | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 167/421 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1243610540, COSV57702143; called by muse, mutect2, varscan2
- TAF1 | c.5228G>A p.R1743H (on ENST00000373790 / NM_138923.4; = p.R1764H on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/225 reads (28%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs758066597; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TANGO6 | c.1171C>T p.R391* | Nonsense Mutation (SNP) | VAF 81/186 reads (44%) | catalogued as rs774043332, COSV55760365; called by muse, mutect2, varscan2
- TARS3 | c.2116G>T p.G706W | Missense Mutation (SNP) | VAF 64/194 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100254486; called by muse, mutect2, varscan2
- TAX1BP1 | c.949C>T p.H317Y | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs184528287, COSV55295992; called by muse, mutect2, varscan2
- TBC1D8 | c.2872+5G>A | Splice Region (SNP) | VAF 73/179 reads (41%) | catalogued as rs764939070; called by muse, mutect2, varscan2
- TBX21 | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 146/427 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.1); catalogued as rs199527603, COSV51597747; called by muse, mutect2, varscan2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 29/95 reads (31%) | catalogued as rs758822980; called by mutect2, varscan2
- TCF20 | c.5826del p.L1943Cfs*118 | Frame Shift Del (DEL) | VAF 40/128 reads (31%) | catalogued as rs756457255; called by mutect2, pindel
- TDRD12 | c.1790del p.N597Ifs*25 | Frame Shift Del (DEL) | VAF 29/66 reads (44%) | catalogued as rs1052864503; called by mutect2, varscan2
- TENM3 | c.7769C>T p.T2590M | Missense Mutation (SNP) | VAF 194/489 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV101305083; called by muse, mutect2, varscan2
- TEP1 | c.1573G>A p.A525T | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52996246; called by muse, mutect2, varscan2
- TLE6 | c.896G>A p.R299Q (on ENST00000246112 / NM_001143986.2; = p.R176Q on NM_024760.3) | Missense Mutation (SNP) | VAF 265/641 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.089); catalogued as rs556698104, COSV55736237; called by muse, mutect2, varscan2
- TLN1 | c.6154G>A p.V2052M | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs763070231; called by muse, mutect2, varscan2
- TLN2 | c.3113C>T p.T1038I | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as rs372847514; called by muse, mutect2, varscan2
- TM4SF5 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 118/297 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749488078; called by muse, mutect2, varscan2
- TMC1 | c.535dup p.S179Kfs*30 | Frame Shift Ins (INS) | VAF 123/421 reads (29%) | catalogued as rs762864983; called by mutect2, pindel, varscan2
- TMEM121B | c.1099G>A p.V367M | Missense Mutation (SNP) | VAF 216/504 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1410685856; called by muse, mutect2, varscan2
- TMEM198 | c.467del p.G156Afs*23 | Frame Shift Del (DEL) | VAF 27/93 reads (29%) | catalogued as rs1310164939, COSV54719891; called by mutect2, pindel, varscan2
- TMEM240 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 173/501 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.026); catalogued as rs779413548; called by muse, mutect2, varscan2
- TMEM40 | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 39/107 reads (36%) | catalogued as rs756191439, COSV53146248; called by muse, mutect2, varscan2
- TMEM94 | c.657del p.F220Sfs*31 | Frame Shift Del (DEL) | VAF 66/210 reads (31%) | catalogued as rs753764149; called by mutect2, pindel, varscan2
- TMEM94 | c.3433dup p.H1145Pfs*2 | Frame Shift Ins (INS) | VAF 59/154 reads (38%) | catalogued as rs752158523; called by mutect2, varscan2
- TNFRSF1A | c.296G>A p.C99Y | Missense Mutation (SNP) | VAF 179/487 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104895231, CM014114; ClinVar: not provided; called by muse, mutect2, varscan2
- TNFRSF9 | c.345del p.G116Vfs*33 | Frame Shift Del (DEL) | VAF 31/85 reads (36%) | catalogued as rs752649731; called by mutect2, pindel, varscan2
- TP53I13 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 68/184 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56402770; called by muse, mutect2, varscan2
- TPPP2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs757325397; called by muse, mutect2, varscan2
- TRAF3IP3 | c.1576C>T p.R526* | Nonsense Mutation (SNP) | VAF 113/418 reads (27%) | catalogued as rs1470581004, COSV50551177; called by muse, mutect2, varscan2
- TRPV6 | c.1799C>T p.A600V | Missense Mutation (SNP) | VAF 126/543 reads (23%) | SIFT tolerated (1); PolyPhen probably damaging (0.92); catalogued as rs1204568429; called by muse, mutect2, varscan2
- TTK | c.2571del p.K857Nfs*36 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | catalogued as rs768996038, COSV57882295; called by mutect2, pindel, varscan2
- TTN | c.90536G>A p.G30179D (on ENST00000591111; = p.G22755D on NM_003319.4) | Missense Mutation (SNP) | VAF 74/186 reads (40%) | PolyPhen possibly damaging (0.755); catalogued as rs1340172871; called by muse, mutect2, varscan2
- UBR2 | c.4277C>T p.A1426V | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs762016028; called by muse, mutect2, varscan2
- UBR4 | c.13504C>T p.R4502C | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64391827; called by muse, mutect2, varscan2
- ULK2 | c.2651A>G p.Q884R | Missense Mutation (SNP) | VAF 81/195 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as rs1192033421; called by muse, mutect2, varscan2
- USF1 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV57035531, COSV57035966; called by muse, mutect2, varscan2
- USP17L1 | c.1357G>A p.G453R | Missense Mutation (SNP) | VAF 272/648 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376292490; called by muse, varscan2
- USP20 | c.1838G>A p.R613H | Missense Mutation (SNP) | VAF 103/300 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.618); catalogued as rs142714756; called by muse, mutect2, varscan2
- VASP | c.721-1G>A p.X241_splice | Splice Site (SNP) | VAF 72/167 reads (43%) | catalogued as COSV55607010, COSV55607761; called by muse, mutect2, varscan2
- VEGFB | c.386del p.K129Rfs*5 | Frame Shift Del (DEL) | VAF 30/78 reads (38%) | catalogued as rs747177567, COSV100374813; called by mutect2, varscan2
- VPS52 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 103/305 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750380612, COSV71403482; called by muse, mutect2, varscan2
- VWA1 | c.462del p.M155Cfs*51 | Frame Shift Del (DEL) | VAF 91/274 reads (33%) | catalogued as rs760281341; called by mutect2, varscan2
- WDR90 | c.844G>A p.G282S | Missense Mutation (SNP) | VAF 102/288 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs529876871; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 22/172 reads (13%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WNK4 | c.2183C>T p.S728L | Missense Mutation (SNP) | VAF 176/438 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.339); catalogued as rs1387533241, COSV55906589; called by muse, mutect2, varscan2
- WNT16 | c.500del p.G167Afs*17 (on ENST00000222462 / NM_057168.2; = p.G157Afs*17 on NM_016087.2) | Frame Shift Del (DEL) | VAF 214/621 reads (34%) | catalogued as rs771899177; called by mutect2, varscan2
- WWOX | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 147/328 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs767286260, COSV68349466, COSV68350177; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- XCR1 | c.40del p.Y14Tfs*33 | Frame Shift Del (DEL) | VAF 35/112 reads (31%) | catalogued as rs1158688440; called by mutect2, pindel, varscan2
- ZBTB22 | c.1504C>T p.R502W | Missense Mutation (SNP) | VAF 145/377 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV56472452; called by muse, mutect2, varscan2
- ZFHX4 | c.9604del p.I3202Sfs*6 | Frame Shift Del (DEL) | VAF 45/116 reads (39%) | catalogued as rs1563570378; called by mutect2, pindel, varscan2
- ZIM2 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 138/328 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV55625593; called by muse, mutect2, varscan2
- ZMYM2 | c.3131del p.K1044Rfs*33 | Frame Shift Del (DEL) | VAF 49/139 reads (35%) | catalogued as rs753611080; called by mutect2, varscan2
- ZNF219 | c.2157dup p.Q720Afs*13 | Frame Shift Ins (INS) | VAF 30/80 reads (38%) | catalogued as rs771569784; called by mutect2, varscan2
- ZNF236 | c.3347C>T p.T1116M | Missense Mutation (SNP) | VAF 127/440 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs376043296, COSV53492563; called by muse, mutect2, varscan2
- ZNF251 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376020478; called by muse, mutect2, varscan2
- ZNF311 | c.1237C>T p.R413* | Nonsense Mutation (SNP) | VAF 177/464 reads (38%) | catalogued as rs749224253; called by muse, mutect2, varscan2
- ZNF354C | c.1514A>G p.Y505C | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1218784626; called by muse, mutect2, varscan2
- ZNF574 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 122/294 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as rs575188445; called by muse, mutect2, varscan2
- ZNF646 | c.2786G>A p.R929H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs377644012; called by muse, mutect2, varscan2
- ZNF691 | c.479G>A p.R160Q (on ENST00000372502; = p.R129Q on NM_015911.3) | Missense Mutation (SNP) | VAF 162/446 reads (36%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.912); catalogued as rs764555560; called by muse, mutect2, varscan2
- ZNF70 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 123/278 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs776168007; called by muse, mutect2, varscan2
- ZNF865 | c.3092G>A p.G1031D | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT tolerated (0.09); catalogued as rs1003939062; called by muse, mutect2, varscan2
- ZXDB | c.389del p.G130Afs*13 | Frame Shift Del (DEL) | VAF 61/175 reads (35%) | catalogued as rs1244764887; called by mutect2, pindel, varscan2
- ABCA6 | c.3246del p.I1082Mfs*19 | Frame Shift Del (DEL) | VAF 36/138 reads (26%) | called by mutect2, pindel, varscan2
- ABCA8 | c.69del p.K23Nfs*4 | Frame Shift Del (DEL) | VAF 33/132 reads (25%) | called by mutect2, pindel, varscan2
- ABHD17A | c.659T>C p.V220A (on ENST00000292577 / NM_001130111.2; = p.V271A on NM_031213.4) | Missense Mutation (SNP) | VAF 183/521 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ABL1 | c.752dup p.Q252Pfs*46 | Frame Shift Ins (INS) | VAF 79/260 reads (30%) | called by mutect2, pindel, varscan2
- ACACB | c.234_235insA p.H79Tfs*30 | Frame Shift Ins (INS) | VAF 77/197 reads (39%) | called by mutect2, pindel, varscan2
- ACSL1 | c.940_942del p.D314del | In Frame Del (DEL) | VAF 51/173 reads (29%) | called by pindel, varscan2
- ACSL4 | c.1821-3del | Splice Region (DEL) | VAF 77/252 reads (31%) | called by mutect2, pindel, varscan2
- ACSM3 | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- ADCY1 | c.2639T>A p.F880Y | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ADGRV1 | c.13607del p.L4536Yfs*17 | Frame Shift Del (DEL) | VAF 42/144 reads (29%) | called by mutect2, pindel
- ADNP | c.2116C>T p.L706F | Missense Mutation (SNP) | VAF 88/291 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- ADSS2 | c.1048C>T p.H350Y | Missense Mutation (SNP) | VAF 62/226 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- AGO2 | c.702_705del p.C235Kfs*15 | Frame Shift Del (DEL) | VAF 26/112 reads (23%) | called by pindel, varscan2
- AIP | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 39/699 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); called by muse, mutect2
- ALG6 | c.315T>A p.S105R | Missense Mutation (SNP) | VAF 134/301 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- AMBP | c.1048T>C p.F350L | Missense Mutation (SNP) | VAF 83/237 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMY2B | c.417G>T p.R139S | Missense Mutation (SNP) | VAF 145/413 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- ANKH | c.317A>G p.Y106C | Missense Mutation (SNP) | VAF 141/402 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKMY2 | c.335_336del p.V112Gfs*15 | Frame Shift Del (DEL) | VAF 47/188 reads (25%) | called by pindel, varscan2
- ANKRD12 | c.6132G>T p.Q2044H | Missense Mutation (SNP) | VAF 73/196 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ANKRD13B | c.1005del p.T336Lfs*26 | Frame Shift Del (DEL) | VAF 51/124 reads (41%) | called by mutect2, pindel, varscan2
- ANKRD24 | c.1742C>T p.A581V | Missense Mutation (SNP) | VAF 93/244 reads (38%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD28 | c.1799A>G p.D600G | Missense Mutation (SNP) | VAF 81/206 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ANKRD35 | c.94dup p.D32Gfs*20 | Frame Shift Ins (INS) | VAF 47/206 reads (23%) | called by mutect2, pindel, varscan2
- AP002512.3 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT tolerated (1); called by muse, mutect2, varscan2
- AP2A1 | c.2513del p.P838Rfs*18 | Frame Shift Del (DEL) | VAF 36/166 reads (22%) | called by mutect2, pindel, varscan2
- APBB2 | c.1097_1104+22del p.X366_splice (on ENST00000295974 / NM_001166050.2; = p.X367_splice on NM_004307.2) | Splice Site (DEL) | VAF 66/176 reads (38%) | called by mutect2, pindel
- APH1A | c.359-3del | Splice Region (DEL) | VAF 55/214 reads (26%) | called by mutect2, pindel, varscan2
- APOBR | c.2255C>T p.A752V (on ENST00000431282; = p.A761V on NM_018690.4) | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- ARHGAP24 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 165/474 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- ARHGAP32 | c.2983G>A p.V995I (on ENST00000310343 / NM_001378025.1; = p.V646I on NM_014715.4) | Missense Mutation (SNP) | VAF 125/252 reads (50%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP42 | c.2540A>G p.Y847C | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGEF17 | c.1850del p.P617Lfs*10 | Frame Shift Del (DEL) | VAF 123/395 reads (31%) | called by mutect2, pindel, varscan2
- ARID1A | c.4244del p.Q1415Rfs*66 | Frame Shift Del (DEL) | VAF 34/122 reads (28%) | called by mutect2, pindel*, varscan2
- ARID4B | c.2705C>T p.A902V | Missense Mutation (SNP) | VAF 80/283 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- ARID5B | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 42/556 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ASS1 | c.916G>C p.V306L | Missense Mutation (SNP) | VAF 298/754 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ASTE1 | c.487T>C p.F163L | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATM | c.1081A>G p.T361A | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ATP6V0A2 | c.76C>A p.L26I | Missense Mutation (SNP) | VAF 36/665 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.023); called by muse, mutect2
- AXDND1 | c.1535T>C p.V512A | Missense Mutation (SNP) | VAF 51/189 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, varscan2
- AXIN1 | c.2053C>T p.P685S | Missense Mutation (SNP) | VAF 103/252 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- B3GALNT1 | c.982A>G p.T328A | Missense Mutation (SNP) | VAF 19/400 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2
- BAG6 | c.344del p.P115Lfs*53 | Frame Shift Del (DEL) | VAF 18/170 reads (11%) | called by mutect2, pindel, varscan2
- BAHCC1 | c.1153del p.R385Gfs*3 | Frame Shift Del (DEL) | VAF 54/133 reads (41%) | called by mutect2, pindel, varscan2
- BECN1 | c.1068dup p.L357Vfs*10 | Frame Shift Ins (INS) | VAF 42/134 reads (31%) | called by mutect2, pindel, varscan2
- BICRA | c.2486del p.P829Qfs*13 | Frame Shift Del (DEL) | VAF 18/59 reads (31%) | called by mutect2, pindel, varscan2
- BIRC6 | c.13397C>G p.A4466G | Missense Mutation (SNP) | VAF 71/234 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BIRC7 | c.463C>T p.L155F | Missense Mutation (SNP) | VAF 28/413 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BMS1 | c.3590C>T p.A1197V | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BPTF | c.5682-1G>A p.X1894_splice | Splice Site (SNP) | VAF 58/124 reads (47%) | called by muse, mutect2, varscan2
- BRAT1 | c.1553A>G p.D518G | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BSN | c.10895A>G p.D3632G | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- BSN | c.11763del p.K3921Nfs*14 | Frame Shift Del (DEL) | VAF 61/208 reads (29%) | called by mutect2, pindel, varscan2
- CACNA1E | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 69/304 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- CAMK2N1 | c.145C>T p.Q49* | Nonsense Mutation (SNP) | VAF 101/257 reads (39%) | called by muse, mutect2, varscan2
- CAMSAP3 | c.297del p.N100Tfs*28 | Frame Shift Del (DEL) | VAF 37/118 reads (31%) | called by mutect2, pindel, varscan2
- CAMSAP3 | c.1874T>C p.F625S | Missense Mutation (SNP) | VAF 23/354 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CANX | c.1305dup p.D436* | Frame Shift Ins (INS) | VAF 80/284 reads (28%) | called by mutect2, varscan2
- CASKIN1 | c.2039G>A p.S680N | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CASP4 | c.1130A>T p.N377I | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CATSPER1 | c.2242dup p.S748Kfs*18 | Frame Shift Ins (INS) | VAF 68/358 reads (19%) | called by pindel, varscan2
- CATSPER1 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- CBLIF | c.833A>C p.K278T | Missense Mutation (SNP) | VAF 127/333 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CC2D1A | c.2759C>T p.A920V | Missense Mutation (SNP) | VAF 163/360 reads (45%) | SIFT tolerated (0.61); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- CCND1 | c.844_870del p.D282_V290del | In Frame Del (DEL) | VAF 32/106 reads (30%) | called by mutect2, pindel
- CD248 | c.2229del p.R744Gfs*61 | Frame Shift Del (DEL) | VAF 37/165 reads (22%) | called by mutect2, pindel, varscan2
- CD8A | c.528del p.L177Wfs*115 | Frame Shift Del (DEL) | VAF 209/635 reads (33%) | called by mutect2, pindel, varscan2
- CDC20 | c.1127del p.G376Afs*18 | Frame Shift Del (DEL) | VAF 81/251 reads (32%) | called by mutect2, pindel, varscan2
- CDH11 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 143/298 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CDHR1 | c.964G>A p.V322M | Missense Mutation (SNP) | VAF 180/473 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CDK5RAP2 | c.3548T>C p.V1183A | Missense Mutation (SNP) | VAF 54/437 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- CENPK | c.232del p.T78Hfs*7 | Frame Shift Del (DEL) | VAF 24/73 reads (33%) | called by mutect2, pindel, varscan2
- CEP162 | c.4016A>G p.Q1339R | Missense Mutation (SNP) | VAF 95/250 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- CEP290 | c.5972dup p.R1992Efs*4 | Frame Shift Ins (INS) | VAF 41/135 reads (30%) | called by mutect2, pindel, varscan2
- CHD9 | c.2280del p.F760Lfs*16 | Frame Shift Del (DEL) | VAF 23/92 reads (25%) | called by mutect2, pindel
- CHMP7 | c.818G>A p.C273Y | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- CLEC14A | c.1363A>G p.S455G | Missense Mutation (SNP) | VAF 71/187 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLEC16A | c.1148G>A p.G383D | Missense Mutation (SNP) | VAF 111/298 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CLVS1 | c.926dup p.H310Afs*30 | Frame Shift Ins (INS) | VAF 36/202 reads (18%) | called by pindel, varscan2
- CNTNAP3B | c.3235A>G p.R1079G | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by mutect2, varscan2
- COG1 | c.2112T>G p.D704E | Missense Mutation (SNP) | VAF 191/536 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL4A2 | c.4264del p.Q1422Rfs*37 | Frame Shift Del (DEL) | VAF 20/67 reads (30%) | called by mutect2, pindel, varscan2
- COL4A3 | c.3408_3409del p.G1137Pfs*19 | Frame Shift Del (DEL) | VAF 158/592 reads (27%) | called by pindel, varscan2
- COL4A5 | c.1247T>A p.I416N | Missense Mutation (SNP) | VAF 85/251 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- COL5A1 | c.3821G>A p.G1274E | Missense Mutation (SNP) | VAF 178/497 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- COL8A1 | c.1795del p.H599Mfs*24 | Frame Shift Del (DEL) | VAF 76/226 reads (34%) | called by mutect2, varscan2
- COMMD9 | c.368T>G p.L123R | Missense Mutation (SNP) | VAF 70/159 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CORIN | c.148G>C p.V50L | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CPN2 | c.370G>T p.G124C | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- CREBRF | c.1538C>T p.T513I | Missense Mutation (SNP) | VAF 66/198 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CRY1 | c.388C>T p.H130Y | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- CTCF | c.610del p.T204Qfs*18 | Frame Shift Del (DEL) | VAF 235/742 reads (32%) | called by mutect2, pindel, varscan2
- CUX2 | c.2603A>G p.Y868C | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- CYP1B1 | c.699del p.T234Rfs*10 | Frame Shift Del (DEL) | VAF 81/392 reads (21%) | called by mutect2, pindel, varscan2
- CYP26B1 | c.11A>G p.E4G | Missense Mutation (SNP) | VAF 135/347 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CYP2C19 | c.707del p.N236Tfs*13 | Frame Shift Del (DEL) | VAF 31/92 reads (34%) | called by mutect2, pindel, varscan2
- CYP2E1 | c.1133del p.F378Sfs*12 | Frame Shift Del (DEL) | VAF 40/118 reads (34%) | called by mutect2, pindel, varscan2
- CYTH2 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- DCPS | c.476G>T p.R159M | Missense Mutation (SNP) | VAF 62/180 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.107); called by muse, mutect2
- DDX19B | c.917C>G p.T306S | Missense Mutation (SNP) | VAF 192/492 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DDX42 | c.647dup p.N216Kfs*5 | Frame Shift Ins (INS) | VAF 39/108 reads (36%) | called by mutect2, varscan2
- DGAT2 | c.1149G>T p.E383D | Missense Mutation (SNP) | VAF 85/200 reads (43%) | SIFT tolerated (0.81); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DGLUCY | c.660G>T p.E220D | Missense Mutation (SNP) | VAF 113/263 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DIDO1 | c.2735C>G p.S912C | Missense Mutation (SNP) | VAF 135/358 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DIMT1 | c.507T>A p.D169E | Missense Mutation (SNP) | VAF 88/259 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DIP2A | c.4247C>T p.A1416V | Missense Mutation (SNP) | VAF 141/396 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- DLC1 | c.2487del p.S830Rfs*7 (on ENST00000276297 / NM_001348081.2; = p.S393Rfs*7 on NM_006094.5) | Frame Shift Del (DEL) | VAF 85/280 reads (30%) | called by mutect2, pindel, varscan2
- DMD | c.10027dup p.S3343Ffs*9 | Frame Shift Ins (INS) | VAF 130/442 reads (29%) | called by mutect2, varscan2
- DNAH11 | c.8603C>T p.A2868V | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH5 | c.6536C>T p.T2179M | Missense Mutation (SNP) | VAF 137/348 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DOK5 | c.803A>G p.Y268C | Missense Mutation (SNP) | VAF 25/266 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- DOP1A | c.5062A>G p.R1688G | Missense Mutation (SNP) | VAF 53/98 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- DST | c.5946del p.S1983Qfs*12 | Frame Shift Del (DEL) | VAF 30/159 reads (19%) | called by mutect2, pindel, varscan2
- DUOXA1 | c.619G>A p.G207S | Missense Mutation (SNP) | VAF 214/552 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- DUSP22 | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- DYNC1H1 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 76/258 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DYNC2I1 | c.1838G>A p.S613N | Missense Mutation (SNP) | VAF 86/246 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, varscan2
- EEF1AKNMT | c.832G>T p.G278W (on ENST00000361735 / NM_015935.5; = p.G192W on NM_014955.3) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, varscan2
- EIF5A | c.381C>A p.Y127* | Nonsense Mutation (SNP) | VAF 105/270 reads (39%) | called by muse, mutect2, varscan2
- EMX2 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 116/319 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- ENGASE | c.322C>A p.L108M | Missense Mutation (SNP) | VAF 246/581 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- EP300 | c.2171del p.P724Lfs*52 | Frame Shift Del (DEL) | VAF 48/217 reads (22%) | called by mutect2, pindel, varscan2
- EPB41L5 | c.1880T>C p.V627A | Missense Mutation (SNP) | VAF 18/310 reads (6%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2
- EPS15 | c.1473+2T>C p.X491_splice | Splice Site (SNP) | VAF 94/282 reads (33%) | called by muse, mutect2, varscan2
- ERBB2 | c.1360G>T p.G454W | Missense Mutation (SNP) | VAF 14/444 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ERBIN | c.2564del p.D855Vfs*14 | Frame Shift Del (DEL) | VAF 59/281 reads (21%) | called by mutect2, pindel, varscan2
- ERI2 | c.133A>G p.T45A | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ERMP1 | c.1022G>A p.G341E | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- EXOSC5 | c.626G>A p.C209Y | Missense Mutation (SNP) | VAF 61/166 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- F2RL3 | c.1084del p.D362Tfs*83 | Frame Shift Del (DEL) | VAF 65/317 reads (21%) | called by mutect2, pindel, varscan2
- FAM118A | c.896T>C p.V299A | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2
- FAM120B | c.1811G>T p.S604I | Missense Mutation (SNP) | VAF 70/226 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM160A2 | c.1702G>A p.A568T (on ENST00000449352 / NM_001098794.2; = p.A582T on NM_032127.4) | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- FAM184B | c.980T>A p.V327D | Missense Mutation (SNP) | VAF 94/277 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- FAM186A | c.2113del p.R705Efs*7 | Frame Shift Del (DEL) | VAF 28/110 reads (25%) | called by mutect2, pindel, varscan2
- FAM189A1 | c.42_43del p.L15Afs*116 | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | called by pindel, varscan2
- FANCA | c.784dup p.M262Nfs*7 | Frame Shift Ins (INS) | VAF 177/768 reads (23%) | called by mutect2, pindel, varscan2
- FBXL18 | c.317G>T p.W106L | Missense Mutation (SNP) | VAF 109/288 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBXO38 | c.2090dup p.N697Kfs*44 | Frame Shift Ins (INS) | VAF 98/252 reads (39%) | called by mutect2, varscan2
- FBXO46 | c.1216G>T p.G406C | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FECH | c.943A>G p.T315A | Missense Mutation (SNP) | VAF 18/249 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FER1L5 | c.3575del p.G1192Dfs*21 (on ENST00000623019; = p.G1165Dfs*21 on NM_001293083.2) | Frame Shift Del (DEL) | VAF 39/119 reads (33%) | called by mutect2, pindel, varscan2
- FIGNL2 | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 130/315 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- FLI1 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 54/217 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- FLNA | c.3884C>T p.A1295V | Missense Mutation (SNP) | VAF 45/281 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FLT4 | c.1267del p.Q423Rfs*70 | Frame Shift Del (DEL) | VAF 162/423 reads (38%) | called by mutect2, varscan2
- FOCAD | c.1531T>C p.Y511H | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FOXC1 | c.1075T>G p.S359A | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- FOXL1 | c.382del p.R128Afs*136 | Frame Shift Del (DEL) | VAF 129/583 reads (22%) | called by mutect2, pindel, varscan2
- FOXP1 | c.80T>C p.L27P | Missense Mutation (SNP) | VAF 199/539 reads (37%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- FSCB | c.1834C>A p.P612T | Missense Mutation (SNP) | VAF 212/583 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.142); called by muse, varscan2
- FUT8 | c.1207del p.R403Efs*12 (on ENST00000360689 / NM_001371534.1; = p.R240Efs*12 on NM_004480.4) | Frame Shift Del (DEL) | VAF 37/135 reads (27%) | called by mutect2, pindel, varscan2
- FYCO1 | c.3190A>G p.S1064G | Missense Mutation (SNP) | VAF 447/1064 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GAPVD1 | c.2139A>C p.E713D | Missense Mutation (SNP) | VAF 65/170 reads (38%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- GAREM2 | c.1124C>A p.P375Q | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- GASK1A | c.490_491del p.Q164Efs*2 | Frame Shift Del (DEL) | VAF 52/169 reads (31%) | called by pindel, varscan2
- GATM | c.1104del p.K368Nfs*60 | Frame Shift Del (DEL) | VAF 70/181 reads (39%) | called by mutect2, pindel, varscan2
- GBF1 | c.3256C>G p.L1086V (on ENST00000369983 / NM_001377137.1; = p.L1085V on NM_004193.3) | Missense Mutation (SNP) | VAF 134/366 reads (37%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- GBP7 | c.1293del p.H432Tfs*5 | Frame Shift Del (DEL) | VAF 96/404 reads (24%) | called by mutect2, varscan2
- GDF1 | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 106/248 reads (43%) | SIFT tolerated (0.1); called by muse, varscan2
- GFPT2 | c.1672C>A p.L558M | Missense Mutation (SNP) | VAF 69/207 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GIGYF1 | c.809del p.G270Efs*75 | Frame Shift Del (DEL) | VAF 69/235 reads (29%) | called by mutect2, pindel, varscan2
- GJC2 | c.1299dup p.K434Efs*58 | Frame Shift Ins (INS) | VAF 105/633 reads (17%) | called by mutect2, pindel, varscan2
- GLCCI1 | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 55/267 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GLRX2 | c.472del p.S158Vfs*22 (on ENST00000367439 / NM_197962.3; = p.S159Vfs*22 on NM_016066.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/83 reads (24%) | called by mutect2, varscan2
- GNAS | c.1969G>A p.A657T | Missense Mutation (SNP) | VAF 14/484 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2
- GNAT3 | c.813del p.D272Ifs*7 | Frame Shift Del (DEL) | VAF 58/150 reads (39%) | called by mutect2, varscan2
- GOLGA4 | c.5004del p.G1669Vfs*6 | Frame Shift Del (DEL) | VAF 57/166 reads (34%) | called by mutect2, pindel, varscan2
- GREM2 | c.403C>T p.L135F | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); called by muse, mutect2
- GRIK4 | c.1078A>G p.T360A | Missense Mutation (SNP) | VAF 144/302 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- GRIN2A | c.4326del p.R1443Gfs*3 | Frame Shift Del (DEL) | VAF 63/221 reads (29%) | called by mutect2, pindel, varscan2
- GRK1 | c.1246C>A p.P416T | Missense Mutation (SNP) | VAF 145/362 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRM5 | c.2636A>G p.K879R | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.931); called by muse, mutect2
- H1-0 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 102/452 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HABP4 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 68/217 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HAPLN1 | c.244A>G p.T82A | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- HBM | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 280/679 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- HEATR6 | c.1837A>G p.N613D | Missense Mutation (SNP) | VAF 18/253 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2
- HELZ2 | c.6638del p.G2213Vfs*22 (on ENST00000467148 / NM_001037335.2; = p.G1644Vfs*22 on NM_033405.3) | Frame Shift Del (DEL) | VAF 28/76 reads (37%) | called by mutect2, pindel, varscan2
- HIP1R | c.358-1G>T p.X120_splice | Splice Site (SNP) | VAF 62/170 reads (36%) | called by muse, mutect2
- HIRIP3 | c.388_390del p.E130del | In Frame Del (DEL) | VAF 60/218 reads (28%) | called by pindel, varscan2
- HIVEP2 | c.1823T>A p.V608D | Missense Mutation (SNP) | VAF 91/220 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HK3 | c.2506dup p.A836Gfs*95 | Frame Shift Ins (INS) | VAF 43/295 reads (15%) | called by mutect2, pindel, varscan2
- HMGB3 | c.533A>G p.K178R | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- HMGN5 | c.825del p.E276Rfs*18 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | called by mutect2, pindel, varscan2
- HMGXB4 | c.689A>G p.D230G | Missense Mutation (SNP) | VAF 64/153 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- HMX3 | c.424G>T p.D142Y | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); called by muse, varscan2
- HNRNPD | c.89T>C p.M30T | Missense Mutation (SNP) | VAF 94/356 reads (26%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HOXA5 | c.761A>T p.N254I | Missense Mutation (SNP) | VAF 94/259 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- HSP90AA1 | c.1973C>A p.S658Y | Missense Mutation (SNP) | VAF 154/452 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ICMT | c.32G>A p.G11D | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- IFITM5 | c.39del p.T14Rfs*24 | Frame Shift Del (DEL) | VAF 26/76 reads (34%) | called by mutect2, pindel, varscan2
- IKBKE | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 31/216 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- IL9R | c.1408C>A p.L470M | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- INPP5D | c.3523C>T p.P1175S (on ENST00000445964 / NM_001017915.3; = p.P1174S on NM_005541.5) | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); called by muse, mutect2
- INPP5F | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 65/186 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- INSR | c.25del p.A9Rfs*56 | Frame Shift Del (DEL) | VAF 29/102 reads (28%) | called by mutect2, pindel, varscan2
- IRF7 | c.115T>C p.C39R (on ENST00000397566; = p.C26R on NM_001572.5) | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ISCU | c.196del p.A66Lfs*7 (on ENST00000311893 / NM_213595.4; = p.A41Lfs*7 on NM_014301.4) | Frame Shift Del (DEL) | VAF 227/603 reads (38%) | called by mutect2, pindel, varscan2
- ISM1 | c.238C>G p.P80A | Missense Mutation (SNP) | VAF 157/502 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ITPKB | c.1579C>T p.Q527* | Nonsense Mutation (SNP) | VAF 44/155 reads (28%) | called by muse, mutect2, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 184/256 reads (72%) | called by mutect2, varscan2
- KAT2B | c.2338A>G p.R780G | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.012); called by muse, varscan2
- KATNIP | c.3248T>A p.I1083K | Missense Mutation (SNP) | VAF 67/240 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KBTBD11 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 104/388 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.058); called by muse, varscan2
- KBTBD3 | c.922A>G p.N308D | Missense Mutation (SNP) | VAF 88/235 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCND3 | c.1613G>A p.S538N | Missense Mutation (SNP) | VAF 297/806 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- KCNH2 | c.2855C>A p.P952H | Missense Mutation (SNP) | VAF 65/158 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- KCNH5 | c.1543A>G p.M515V | Missense Mutation (SNP) | VAF 106/313 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- KCNH7 | c.3447T>A p.D1149E | Missense Mutation (SNP) | VAF 80/223 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KDM8 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 103/291 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- KERA | c.459G>T p.K153N | Missense Mutation (SNP) | VAF 62/191 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- KIF3C | c.845C>G p.A282G | Missense Mutation (SNP) | VAF 35/299 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF4A | c.3268G>T p.G1090C | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- KLHL23 | c.306_308del p.T103del | In Frame Del (DEL) | VAF 38/117 reads (32%) | called by mutect2, pindel, varscan2
- KLHL31 | c.1559G>A p.G520D | Missense Mutation (SNP) | VAF 133/357 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMT2A | c.1660del p.Q554Sfs*13 | Frame Shift Del (DEL) | VAF 107/296 reads (36%) | called by mutect2, pindel, varscan2
- KMT2B | c.649del p.R217Gfs*22 | Frame Shift Del (DEL) | VAF 47/127 reads (37%) | called by mutect2, pindel, varscan2
- KMT2B | c.3302del p.P1101Lfs*81 | Frame Shift Del (DEL) | VAF 36/95 reads (38%) | called by mutect2, pindel, varscan2
- KMT2D | c.7061del p.P2354Lfs*30 | Frame Shift Del (DEL) | VAF 97/274 reads (35%) | called by mutect2, pindel, varscan2
- KMT2D | c.1966dup p.L656Pfs*12 | Frame Shift Ins (INS) | VAF 12/42 reads (29%) | called by mutect2, pindel, varscan2
- KMT2E | c.340T>C p.Y114H | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- KRT24 | c.223G>A p.G75S | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- LAMA5 | c.10495A>G p.R3499G | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LIMS1 | c.604G>T p.G202W | Missense Mutation (SNP) | VAF 78/234 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LOXHD1 | c.862G>A p.V288M | Missense Mutation (SNP) | VAF 112/240 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRFN4 | c.246T>A p.N82K | Missense Mutation (SNP) | VAF 158/355 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP1 | c.13258+1G>A p.X4420_splice | Splice Site (SNP) | VAF 123/296 reads (42%) | called by muse, mutect2, varscan2
- LRP2 | c.7780C>T p.H2594Y | Missense Mutation (SNP) | VAF 148/355 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LYSMD1 | c.36del p.S13Qfs*23 | Frame Shift Del (DEL) | VAF 75/304 reads (25%) | called by mutect2, pindel, varscan2
- MAGEB1 | c.606G>T p.M202I | Missense Mutation (SNP) | VAF 8/235 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); called by muse, mutect2
- MAGEB6B | c.814A>G p.N272D | Missense Mutation (SNP) | VAF 123/305 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAIP1 | c.820G>T p.G274* | Nonsense Mutation (SNP) | VAF 44/124 reads (35%) | called by muse, mutect2, varscan2
- MAP3K5 | c.4115_4118del p.K1372Rfs*8 | Frame Shift Del (DEL) | VAF 79/242 reads (33%) | called by pindel, varscan2
- MAP3K9 | c.2022G>T p.E674D | Missense Mutation (SNP) | VAF 64/293 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- MAS1L | c.1076A>G p.H359R | Missense Mutation (SNP) | VAF 75/169 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- MCF2L | c.1885G>A p.A629T (on ENST00000375608; = p.A597T on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/217 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MIA2 | c.176dup p.L59Ffs*6 | Frame Shift Ins (INS) | VAF 62/168 reads (37%) | called by mutect2, varscan2
- MID2 | c.1741G>C p.A581P | Missense Mutation (SNP) | VAF 92/323 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- MKNK2 | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 61/177 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- MOB4 | c.318G>A p.W106* | Nonsense Mutation (SNP) | VAF 37/121 reads (31%) | called by muse, mutect2, varscan2
- MOV10L1 | c.1387A>G p.K463E | Missense Mutation (SNP) | VAF 66/207 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MREG | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MROH9 | c.1426C>T p.Q476* | Nonsense Mutation (SNP) | VAF 50/218 reads (23%) | called by muse, mutect2, varscan2
- MS4A10 | c.133C>T p.H45Y | Missense Mutation (SNP) | VAF 111/242 reads (46%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- MS4A6A | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- MTA1 | c.1805C>A p.P602H | Missense Mutation (SNP) | VAF 100/239 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MTNR1A | c.172C>T p.L58F | Missense Mutation (SNP) | VAF 139/367 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- MTOR | c.7180G>A p.G2394S | Missense Mutation (SNP) | VAF 79/169 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTSS1 | c.880T>C p.S294P | Missense Mutation (SNP) | VAF 204/485 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MUC16 | c.33676A>G p.T11226A | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- MUC16 | c.26367dup p.K8790Qfs*48 | Frame Shift Ins (INS) | VAF 63/188 reads (34%) | called by mutect2, pindel, varscan2
- MUC5B | c.2107T>C p.Y703H | Missense Mutation (SNP) | VAF 108/252 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- MYH7B | c.510G>A p.W170* | Nonsense Mutation (SNP) | VAF 12/208 reads (6%) | called by muse, mutect2
- MYH8 | c.2354C>T p.A785V | Missense Mutation (SNP) | VAF 125/374 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYH9 | c.2287_2289del p.F763del | In Frame Del (DEL) | VAF 194/504 reads (38%) | called by pindel, varscan2
- MYO10 | c.4612C>A p.H1538N | Missense Mutation (SNP) | VAF 85/215 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- MYO16 | c.4490dup p.T1498Dfs*205 | Frame Shift Ins (INS) | VAF 10/59 reads (17%) | called by mutect2, pindel, varscan2
- MYO1F | c.2228A>G p.Y743C | Missense Mutation (SNP) | VAF 35/746 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NCKAP1L | c.1328A>G p.D443G | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- NEB | c.9565A>T p.T3189S | Missense Mutation (SNP) | VAF 45/372 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- NEB | c.732del p.G245Vfs*18 | Frame Shift Del (DEL) | VAF 158/495 reads (32%) | called by mutect2, pindel, varscan2
- NEMP1 | c.607A>G p.I203V (on ENST00000300128 / NM_001130963.2; = p.I130V on NM_015257.3) | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NKAIN4 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 77/194 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- NKX1-1 | c.1133C>T p.T378M | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- NLGN3 | c.1345A>G p.T449A (on ENST00000358741 / NM_181303.2; = p.T429A on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 210/769 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NLRX1 | c.2393T>C p.V798A | Missense Mutation (SNP) | VAF 94/263 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NMT1 | c.1360G>A p.D454N | Missense Mutation (SNP) | VAF 88/195 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- NOS2 | c.66del p.D23Tfs*17 | Frame Shift Del (DEL) | VAF 84/301 reads (28%) | called by mutect2, pindel, varscan2
- NPFFR1 | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 24/340 reads (7%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.992); called by muse, mutect2
- NR0B1 | c.926T>C p.V309A | Missense Mutation (SNP) | VAF 164/711 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- NSD1 | c.4591del p.M1531Cfs*43 | Frame Shift Del (DEL) | VAF 213/690 reads (31%) | called by mutect2, pindel, varscan2
- NYAP2 | c.945del p.K316Rfs*57 | Frame Shift Del (DEL) | VAF 30/100 reads (30%) | called by mutect2, pindel
- OBI1 | c.776del p.N259Ifs*9 | Frame Shift Del (DEL) | VAF 16/139 reads (12%) | called by mutect2, pindel, varscan2
- OBSCN | c.16445T>C p.L5482P | Missense Mutation (SNP) | VAF 73/328 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OCRL | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 121/515 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- OCRL | c.1709G>T p.R570M | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- OGT | c.629C>A p.A210E | Missense Mutation (SNP) | VAF 76/144 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- ONECUT2 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR10V1 | c.401G>T p.R134M | Missense Mutation (SNP) | VAF 86/226 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- OR12D3 | c.544C>T p.L182F | Missense Mutation (SNP) | VAF 79/181 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2J2 | c.777G>A p.M259I | Missense Mutation (SNP) | VAF 81/241 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4F6 | c.272C>T p.T91I | Missense Mutation (SNP) | VAF 11/282 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); called by muse, mutect2
- OR4N2 | c.469A>G p.I157V | Missense Mutation (SNP) | VAF 122/490 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- OR5V1 | c.548dup p.L184Ffs*13 | Frame Shift Ins (INS) | VAF 53/183 reads (29%) | called by mutect2, pindel, varscan2
- OVGP1 | c.1998del p.E667Kfs*30 | Frame Shift Del (DEL) | VAF 12/98 reads (12%) | called by mutect2, pindel
- OXNAD1 | c.653dup p.N218Kfs*8 | Frame Shift Ins (INS) | VAF 46/142 reads (32%) | called by mutect2, pindel
- PATZ1 | c.1724A>G p.K575R | Missense Mutation (SNP) | VAF 146/388 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PAX2 | c.1207del p.R403Gfs*37 (on ENST00000428433 / NM_003987.5; = p.R380Gfs*37 on NM_000278.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 157/507 reads (31%) | called by mutect2, pindel, varscan2
- PAXBP1 | c.1594C>T p.R532W | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH1 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- PCDH15 | c.737C>T p.T246I | Missense Mutation (SNP) | VAF 184/534 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDHA2 | c.1006del p.I336Ffs*3 | Frame Shift Del (DEL) | VAF 78/223 reads (35%) | called by mutect2, pindel, varscan2
- PCNX4 | c.2570_2572del p.V857del (on ENST00000406854 / NM_001330177.2; = p.V623del on NM_022495.5) | In Frame Del (DEL) | VAF 57/170 reads (34%) | called by mutect2, pindel, varscan2
- PCOLCE | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 69/213 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDE5A | c.1916C>T p.T639I | Missense Mutation (SNP) | VAF 115/304 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- PDZD8 | c.3346del p.I1116* | Frame Shift Del (DEL) | VAF 65/228 reads (29%) | called by mutect2, pindel, varscan2
- PF4V1 | c.100+2T>C p.X34_splice | Splice Site (SNP) | VAF 28/260 reads (11%) | called by muse, mutect2, varscan2
- PGBD2 | c.1102del p.V368* | Frame Shift Del (DEL) | VAF 71/479 reads (15%) | called by mutect2, pindel, varscan2
- PHF20 | c.2191T>G p.Y731D | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PICALM | c.329dup p.L110Ffs*3 | Frame Shift Ins (INS) | VAF 31/90 reads (34%) | called by mutect2, pindel, varscan2
- PIGO | c.1052del p.G351Vfs*11 | Frame Shift Del (DEL) | VAF 64/217 reads (29%) | called by mutect2, pindel, varscan2
- PIM3 | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 80/208 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, varscan2
- PIP4K2A | c.237del p.F79Lfs*38 | Frame Shift Del (DEL) | VAF 68/199 reads (34%) | called by mutect2, pindel, varscan2
- PKD2L2 | c.1245del p.F415Lfs*2 | Frame Shift Del (DEL) | VAF 84/279 reads (30%) | called by mutect2, pindel, varscan2
- PLA2G6 | c.1177del p.I393Sfs*11 | Frame Shift Del (DEL) | VAF 220/672 reads (33%) | called by mutect2, pindel, varscan2
- PLCL2 | c.3275C>T p.A1092V (on ENST00000615277 / NM_001144382.2; = p.A966V on NM_015184.5) | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- PLIN5 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- PLS3 | c.1611del p.K537Nfs*22 | Frame Shift Del (DEL) | VAF 72/211 reads (34%) | called by mutect2, pindel, varscan2
- POR | c.974T>C p.V325A | Missense Mutation (SNP) | VAF 151/368 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- POU3F1 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PPM1E | c.2246C>A p.P749H | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRAM1 | c.1264G>T p.G422C | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- PRKCSH | c.386A>G p.Q129R | Missense Mutation (SNP) | VAF 204/535 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRPF39 | c.1437G>T p.Q479H | Missense Mutation (SNP) | VAF 38/417 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); called by muse, mutect2
- PSMB7 | c.215A>G p.K72R | Missense Mutation (SNP) | VAF 69/190 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- PSMG1 | c.580del p.T194Hfs*13 | Frame Shift Del (DEL) | VAF 124/374 reads (33%) | called by mutect2, pindel, varscan2
- PTGDR2 | c.698T>C p.L233S | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- PTPN13 | c.4354G>T p.G1452* (on ENST00000411767 / NM_080683.3; = p.G1433* on NM_006264.3) | Nonsense Mutation (SNP) | VAF 48/125 reads (38%) | called by muse, mutect2, varscan2
- PTPRM | c.3749G>A p.S1250N | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- PTPRZ1 | c.790del p.C264Vfs*14 | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | called by mutect2, pindel
- PTPRZ1 | c.5804C>T p.A1935V | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PURA | c.897_899del p.Q303del | In Frame Del (DEL) | VAF 20/68 reads (29%) | called by pindel, varscan2
- RAPGEF6 | c.3388A>G p.M1130V | Missense Mutation (SNP) | VAF 74/194 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RB1CC1 | c.2736A>C p.E912D | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- RBM6 | c.1024G>A p.G342R | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- RBMS1 | c.35A>G p.Q12R | Missense Mutation (SNP) | VAF 73/222 reads (33%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RC3H1 | c.1424C>A p.A475D | Missense Mutation (SNP) | VAF 142/509 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- RESF1 | c.1846A>T p.M616L | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- REV1 | c.1641G>T p.K547N | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- RGS9 | c.1291T>C p.S431P | Missense Mutation (SNP) | VAF 104/403 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- RIMKLB | c.683G>A p.S228N | Missense Mutation (SNP) | VAF 14/334 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); called by muse, mutect2
- RNASET2 | c.336G>C p.K112N | Missense Mutation (SNP) | VAF 146/426 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- RNF215 | c.1011G>A p.W337* | Nonsense Mutation (SNP) | VAF 82/185 reads (44%) | called by muse, mutect2, varscan2
- RNPS1 | c.509G>T p.R170L | Missense Mutation (SNP) | VAF 134/276 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ROS1 | c.4645A>T p.I1549F | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- RPF1 | c.285+2T>C p.X95_splice | Splice Site (SNP) | VAF 31/91 reads (34%) | called by muse, mutect2, varscan2
- RRM1 | c.320C>A p.P107Q | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- RUBCN | c.1682G>A p.G561E | Missense Mutation (SNP) | VAF 115/310 reads (37%) | SIFT tolerated (0.75); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- RWDD3 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.657); called by muse, varscan2
557 further variants in this file (125 protein-altering or splice-affecting, 262 silent, 170 other) are not listed here.
